Somatic mutation profile of tumor specimen 0DPZTP from CCDI case PBCBKH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Myxofibrosarcoma; Tissue or organ of origin: Skin of lower limb and hip; Age at diagnosis: 15.0 years (5,492 days).
Specimen 0DPZTP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1102dd09-3525-4962-84a3-b22a6fbe9f83.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPZU8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/422124db-40b1-4a0e-a9a2-e7220b10f286

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DAPK1 | c.565G>T p.V189F | Missense Mutation (SNP) | VAF 153/318 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63787324; called by muse, varscan2
- CCSER1 | c.460T>C p.S154P | Missense Mutation (SNP) | VAF 130/338 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, varscan2
- NLGN2 | c.2285G>T p.R762L | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, varscan2
